Somatic mutation profile of tumor specimen MMRF_2239_1_BM_CD138pos (aliquot MMRF_2239_1_BM_CD138pos_T1_KHS5U_K15222) from MMRF case MMRF_2239, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.1 years (27,083 days).
Specimen MMRF_2239_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5482183-8226-44ff-b12f-df30f51f7554.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2239_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2239_1_PB_Whole_C2_KHS5U_K15209; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ca34710-9279-4b26-9b3f-d5086afa6318

The open-access MAF lists 97 somatic variants for this specimen: 37 protein-altering or splice-affecting, 13 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 23, Intron 15, Silent 13, 5'UTR 4, 3'Flank 3, Frame Shift Del 1, 5'Flank 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 26/76 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCA12 | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 101/185 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as COSV55953180; called by muse, mutect2, varscan2
- ADAMTS2 | c.1042C>T p.L348F | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV99204818; called by muse, mutect2, varscan2
- ANO1 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 94/251 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs868476909, COSV100796879; called by muse, mutect2, varscan2
- C4orf54 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.871); catalogued as rs539120754; called by muse, mutect2, varscan2
- CACNA2D1 | c.3097C>T p.Q1033* (on ENST00000356253 / NM_001366867.1; = p.Q1021* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 43/168 reads (26%) | catalogued as rs1554327240; called by muse, mutect2, varscan2
- CDC6 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1353466345; called by muse, mutect2, varscan2
- ELP3 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 9/303 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1266456486, COSV56461357; called by muse, mutect2
- ERG | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs200306085, COSV55732038; called by muse, mutect2, varscan2
- IGLV3-1 | c.251A>T p.N84I | Missense Mutation (SNP) | VAF 200/274 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs373605544; called by muse, mutect2, varscan2
- LGALS12 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 121/218 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs768128889; called by muse, mutect2, varscan2
- LOXL1 | c.1576G>A p.V526M | Missense Mutation (SNP) | VAF 115/415 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs368697216; called by muse, mutect2, varscan2
- MME | c.1471A>G p.N491D | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs776985438; called by muse, mutect2, varscan2
- NRG1 | c.1624G>A p.A542T (on ENST00000405005 / NM_013964.5; = p.A547T on NM_013956.5) | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs776391266, COSV55154820; called by muse, mutect2, varscan2
- OR10W1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs772973050; called by muse, mutect2, varscan2
- THSD7B | c.3753G>T p.Q1251H (on ENST00000272643; = p.Q1249H on NM_001316349.2) | Missense Mutation (SNP) | VAF 54/87 reads (62%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.754); catalogued as rs766000157; called by muse, mutect2, varscan2
- TIMP4 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs755266079, COSV99826000; called by muse, mutect2, varscan2
- TMEM161A | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1194790043, COSV50776202; called by muse, mutect2
- TRPM3 | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 31/306 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs895430510; called by muse, mutect2
- ZSCAN18 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1330853622, COSV99559617; called by muse, mutect2, varscan2
- AHNAK | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AKAP13 | c.3980C>G p.A1327G | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- ARHGDIG | c.612C>A p.D204E | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1H | c.6548G>C p.R2183T | Missense Mutation (SNP) | VAF 86/211 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- DNM2 | c.2276G>C p.S759T (on ENST00000355667 / NM_001005360.3; = p.S755T on NM_004945.3) | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); called by muse, mutect2
- ERVV-1 | c.1067T>G p.I356R | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- KCTD3 | c.1011A>G p.I337M | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- MAP4K4 | c.3620G>A p.C1207Y (on ENST00000347699 / NM_001242559.2; = p.C1133Y on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MRPL24 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MYBPC1 | c.2335G>A p.A779T | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.97); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- NDST1 | c.83T>G p.L28R | Missense Mutation (SNP) | VAF 104/313 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- PCDHGB6 | c.481G>C p.D161H | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNPLA8 | c.154A>G p.T52A | Missense Mutation (SNP) | VAF 114/413 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RHOXF2 | c.458T>C p.F153S | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENT5C | c.384_385del p.K128Nfs*22 | Frame Shift Del (DEL) | VAF 44/110 reads (40%) | called by mutect2, pindel, varscan2
- TNRC6B | c.2665A>G p.I889V | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- WDR17 | c.2605G>C p.D869H | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- ABCD3 | c.777A>G p.Q259= | Silent (SNP) | VAF 61/114 reads (54%) | called by muse, varscan2
- ADGRL2 | c.195T>A p.G65= | Silent (SNP) | VAF 83/177 reads (47%) | called by muse, mutect2, varscan2
- EPHA3 | c.2295C>T p.F765= | Silent (SNP) | VAF 42/64 reads (66%) | catalogued as rs773426684, COSV60694998; called by muse, mutect2, varscan2
- FEM1A | c.1203C>T p.A401= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs1251424044; called by muse, mutect2, varscan2
- GID4 | c.258C>G p.V86= | Silent (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- IGLL5 | c.132A>T p.A44= | Silent (SNP) | VAF 40/55 reads (73%) | catalogued as rs559053132, COSV73250410, COSV73251264; called by muse, mutect2, varscan2
- LONRF3 | c.24G>A p.Q8= | Silent (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- MIS18BP1 | c.3075A>G p.P1025= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs1362570849; called by muse, mutect2, varscan2
- RTL1 | c.2940C>T p.D980= | Silent (SNP) | VAF 97/194 reads (50%) | called by muse, mutect2, varscan2
- TEKT2 | c.1092C>T p.D364= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as rs775161619, COSV52881395; called by muse, mutect2, varscan2
- TEX264 | c.210C>T p.I70= | Silent (SNP) | VAF 57/182 reads (31%) | called by muse, mutect2, varscan2
- THRB | c.612G>T p.L204= | Silent (SNP) | VAF 94/305 reads (31%) | called by muse, mutect2, varscan2
- ZAN | c.7563G>A p.A2521= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as rs369536919; called by muse, mutect2, varscan2
- AC244517.10 | c.36-10097T>C | Intron (SNP) | VAF 58/180 reads (32%) | called by muse, mutect2, varscan2
- ADCY1 | c.*131G>A | 3'UTR (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.*2358A>G | 3'UTR (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- ADH6 | chr4:99204180 G>T | 3'Flank (SNP) | VAF 107/257 reads (42%) | called by muse, mutect2, varscan2
- ARHGAP10 | c.598-70G>T | Intron (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- ART4 | c.-97C>T | 5'UTR (SNP) | VAF 32/61 reads (52%) | catalogued as rs951100248, COSV57453890; called by muse, mutect2, varscan2
- BNIP2 | c.472+822G>A | Intron (SNP) | VAF 24/91 reads (26%) | called by muse, mutect2, varscan2
- C8orf74 | c.242-4714C>T | Intron (SNP) | VAF 25/58 reads (43%) | catalogued as rs1156930433; called by muse, mutect2, varscan2
- CAMK4 | c.*6801_*6802del | 3'UTR (DEL) | VAF 42/123 reads (34%) | called by mutect2, pindel, varscan2
- CAMLG | c.-14C>T | 5'UTR (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- CCAR1 | c.2880+40T>A | Intron (SNP) | VAF 4/11 reads (36%) | called by muse, varscan2
- CHRNA5 | c.*1681T>C | 3'UTR (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- CNOT1 | c.*118T>G | 3'UTR (SNP) | VAF 50/95 reads (53%) | called by muse, mutect2, varscan2
- CWC25 | c.-119C>T | 5'UTR (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- DDX5 | c.211-131A>G | Intron (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- FAM102B | c.*2874T>A | 3'UTR (SNP) | VAF 34/63 reads (54%) | called by muse, mutect2, varscan2
- FOXL1 | c.*1334C>T | 3'UTR (SNP) | VAF 16/47 reads (34%) | catalogued as rs1206426487, COSV57215034; called by muse, mutect2, varscan2
- FOXL2 | c.-194G>A | 5'UTR (SNP) | VAF 20/79 reads (25%) | catalogued as rs928301280; called by muse, mutect2, varscan2
- GFRA2 | chr8:21691256 G>A | 3'Flank (SNP) | VAF 49/135 reads (36%) | catalogued as rs933831209; called by muse, mutect2, varscan2
- GLB1L | c.239+51C>T | Intron (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- HNRNPA0 | c.*551dup | 3'UTR (INS) | VAF 14/38 reads (37%) | called by mutect2, varscan2
- HSD17B7P2 | n.719C>T | RNA (SNP) | VAF 50/138 reads (36%) | catalogued as rs1406330564; called by muse, mutect2, varscan2
- ITPK1 | c.*96G>C | 3'UTR (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- NDST1 | c.*3481A>G | 3'UTR (SNP) | VAF 69/231 reads (30%) | called by muse, mutect2, varscan2
- OR56A1 | c.-34-11C>T | Intron (SNP) | VAF 55/164 reads (34%) | called by muse, mutect2, varscan2
- PCGF3 | c.*3759C>T | 3'UTR (SNP) | VAF 13/30 reads (43%) | catalogued as rs769138882; called by muse, mutect2
- PKN2 | c.1677-100T>C | Intron (SNP) | VAF 38/79 reads (48%) | called by muse, mutect2, varscan2
- POGLUT1 | c.85+14A>G | Intron (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- PPP3CA | chr4:101348537 G>C | 5'Flank (SNP) | VAF 91/214 reads (43%) | called by muse, mutect2, varscan2
- PRR30 | c.*214G>A | 3'UTR (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- RABGAP1L | c.2212-11698C>T | Intron (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- RAD52 | c.*315_*331del | 3'UTR (DEL) | VAF 3/27 reads (11%) | called by pindel, varscan2*
- SAPCD2 | c.*987C>T | 3'UTR (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- SBDS | c.*63A>G | 3'UTR (SNP) | VAF 183/646 reads (28%) | called by muse, mutect2, varscan2
- SETD1A | c.*387C>T | 3'UTR (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- SF3A3 | c.*1036A>C | 3'UTR (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- SLC12A3 | c.2924+36T>C | Intron (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- SLC7A2 | c.*2055A>G | 3'UTR (SNP) | VAF 25/63 reads (40%) | catalogued as rs901384169; called by muse, mutect2, varscan2
- STXBP5L | c.*1501G>A | 3'UTR (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- TRAF3 | c.*3817del | 3'UTR (DEL) | VAF 37/101 reads (37%) | called by mutect2, pindel, varscan2
- TRPC3 | c.216-12G>T | Intron (SNP) | VAF 58/181 reads (32%) | called by muse, mutect2, varscan2
- UBXN2A | c.287+43C>T | Intron (SNP) | VAF 23/41 reads (56%) | catalogued as rs754215134; called by muse, mutect2, varscan2
- YIPF7 | chr4:44622230 A>G | 3'Flank (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- ZDHHC3 | c.*9576A>G | 3'UTR (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2, varscan2
- ZFP42 | c.*1054dup | 3'UTR (INS) | VAF 8/28 reads (29%) | catalogued as rs1191896217; called by mutect2, varscan2
- ZNF385D | c.*1573C>G | 3'UTR (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- ZNF485 | c.24+41C>T | Intron (SNP) | VAF 28/72 reads (39%) | catalogued as rs1396120148; called by muse, mutect2, varscan2
